Somatic mutation profile of tumor specimen TCGA-EJ-A7NH-01A (aliquot TCGA-EJ-A7NH-01A-12D-A33T-08) from TCGA case TCGA-EJ-A7NH, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.8 years (20,734 days).
Specimen TCGA-EJ-A7NH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd2fc723-2852-4d66-a9e8-caaccaedc357.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A7NH-10A (Blood Derived Normal), aliquot TCGA-EJ-A7NH-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a46f1ff-afd0-4ec9-8b2c-486284e3e28e

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.487T>C p.Y163H | Missense Mutation (SNP) | VAF 5/68 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786203436, COSV52661160, COSV52676168, COSV52853225, COSV53025600; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- ABHD14A-ACY1 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0); catalogued as COSV99865614; called by muse, mutect2, varscan2
- ADGRB3 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV101002013; called by muse, mutect2, varscan2
- ASB9 | c.306G>A p.W102* | Nonsense Mutation (SNP) | VAF 3/50 reads (6%) | catalogued as COSV66852070; called by muse, mutect2
- CHAF1A | c.1957G>A p.D653N | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs768790348, COSV100011486; called by muse, mutect2, varscan2
- CHD2 | c.2954G>C p.G985A | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV101246055; called by muse, mutect2
- DGKI | c.2095G>A p.A699T | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99934776; called by muse, mutect2, varscan2
- DLG4 | c.832C>A p.L278M (on ENST00000399506 / NM_001321075.3; = p.L321M on NM_001365.4) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.065); catalogued as COSV57239042; called by muse, mutect2
- EIF3L | c.411C>G p.Y137* | Nonsense Mutation (SNP) | VAF 37/218 reads (17%) | catalogued as COSV101094718; called by muse, mutect2, varscan2
- GAD1 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs201232271; called by muse, mutect2, varscan2
- KMT2C | c.8953C>T p.Q2985* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100076813; called by muse, mutect2, varscan2
- PFKM | c.2111C>T p.T704I | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as COSV100402759; called by muse, mutect2, varscan2
- SLC35F3 | c.502T>G p.Y168D (on ENST00000366617 / NM_001300845.1; = p.Y237D on NM_173508.4) | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100784859; called by muse, mutect2
- SPTAN1 | c.4280G>A p.R1427H | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as rs762216368, COSV100824046; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TFEC | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1488972734, COSV99624996; called by muse, mutect2, varscan2
- APBA1 | c.1026G>A p.K342= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as rs1289251009, COSV99597188; called by muse, mutect2, varscan2
- COX7A2 | c.198G>A p.L66= | Silent (SNP) | VAF 16/161 reads (10%) | catalogued as COSV100034563; called by muse, mutect2, varscan2
- TBX18 | c.1332G>A p.Q444= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV100858443, COSV100858590; called by muse, mutect2, varscan2
